Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A3BO, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A3BO-01A (Primary Tumor).

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

1) THYROID:

SPECIMEN TYPE:

Total thyroidectomy

TUMOR SITE:

Left and right lobes

HISTOLOGIC TYPE:

Papillary carcinoma with tall cell features

TUMOR SIZES:

2.5 cm and 2.2 cm, left lobe; 0.2 cm and 0.2 cm, right lobe.

FOCALITY:

Multifocal.

LYMPH NODES:

Metastatic carcinoma in 2 of 10 lymph nodes (includes
has two lymph nodes).

which

EXTENT OF INVASION

PRIMARY TUMOR:

pT3: Tumor with minimal extrathyroidal extension

REGIONAL LYMPH NODES:

pN1a: Nodal metastasis to level VI (pretracheal, paratracheal, and
prelaryngeal/Delphian) nodes

MARGINS:

Focally involved by invasive carcinoma

Specify margin: left inferior pole

VENOUS/LYMPHATIC INVASION:

Indeterminate

ADDITIONAL PATHOLOGIC FINDINGS:

Hashimoto thyroiditis

NOTE: One parathyroid gland is identified (right side).

103-0-3

carcinoma, papillary, tall cell variant
8344/3

Site: Thyroid, NOS C73.9

10/15/11

Source: NCI Genomic Data Commons file 75eb7e14-8ec1-4528-9316-7c03f1e261b1 (TCGA-ET-A3BO.EA12FC89-CE8B-4829-BDD1-F5315EAC4B5F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).